Somatic mutation profile of tumor specimen TCGA-XE-AAO3-01A (aliquot TCGA-XE-AAO3-01A-11D-A435-10) from TCGA case TCGA-XE-AAO3, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 33.1 years (12,095 days).
Specimen TCGA-XE-AAO3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0830177-3dfb-4167-a543-38a4c8044d1f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XE-AAO3-10A (Blood Derived Normal), aliquot TCGA-XE-AAO3-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f4d8997-fa3c-4186-97d1-edaae41893f4

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 2, Splice Site 1, Frame Shift Del 1, RNA 1, In Frame Del 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPL | c.1564_1566del p.E522del | In Frame Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs754998388; called by mutect2, pindel, varscan2
- SYNGAP1 | c.3409-1G>A p.X1137_splice | Splice Site (SNP) | VAF 4/98 reads (4%) | catalogued as COSV53381614; called by muse, mutect2
- ATAD5 | c.3300T>A p.D1100E | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATP4A | c.1115T>C p.L372P | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DTNB | c.1352T>A p.L451Q | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- EPOP | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.034); called by muse, mutect2
- EXOC3L1 | c.1908C>T p.G636= | Splice Region (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- MARCHF6 | c.2000C>G p.T667R | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- MFSD2B | c.1411G>C p.A471P | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- SCN10A | c.1870C>A p.L624I | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); called by muse, mutect2
- SKIV2L | c.2866C>T p.P956S | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- TAS2R40 | c.670_671del p.T224Pfs*48 | Frame Shift Del (DEL) | VAF 19/102 reads (19%) | called by pindel, varscan2
- VPS13B | c.7045C>T p.L2349F | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KYNU | c.318G>A p.K106= | Silent (SNP) | VAF 19/101 reads (19%) | catalogued as rs779376309, COSV51584058; called by muse, mutect2, varscan2
- SYNCRIP | c.525G>A p.E175= | Silent (SNP) | VAF 58/245 reads (24%) | called by muse, mutect2, varscan2
- PRPF31 | c.855+49C>T | Intron (SNP) | VAF 12/31 reads (39%) | catalogued as rs781007230; called by muse, mutect2, varscan2
- SSPOP | n.4487C>T | RNA (SNP) | VAF 18/77 reads (23%) | catalogued as rs1362626689; called by muse, mutect2, varscan2
